CPTAC case C3L-00360 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b1114673-0f13-4265-98d8-21c5714d91a4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 72.3 years (26,395 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,780 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,780 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 252 days; Disease response: Tumor Free.
- Days to follow up: 672 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,014 days (2.8 years); Disease response: Tumor Free.
- Days to follow up: 1,417 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,780 days (4.9 years); Disease response: Tumor Free.
- Days to follow up: 1,780 days (4.9 years); Disease response: Complete Response.

Other clinical attributes
- Weight: 122 kg; Height: 177 cm; BMI: 38.94.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Cigarettes per day: 20; Tobacco smoking onset year: 1963; Tobacco smoking quit year: 2003; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 40.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00360-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 267 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00360-21: Section location: posterior central; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-00360-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 204 mg.
- Sample C3L-00360-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 220 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00360-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3L-00360-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
